HCMI case HCM-CSHL-0510-D13 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Small intestine. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6380f4ca-f7ca-41ee-90ed-54403bed84f6

Demographics
Sex at birth: female; Year of birth: 1960; Vital status: Alive.

Diagnoses (1)
1. Tubulovillous adenoma, NOS: ICD-O-3 morphology code: 8263/0; ICD-10 code: D13; Tissue or organ of origin: Small intestine, NOS; Site of resection or biopsy: Duodenum; Classification of tumor: Premalignant; Age at diagnosis: 59.1 years (21,570 days); AJCC staging edition: 8th; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: GX; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 64; Lymphatic invasion present: No; Necrosis present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -10 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (2 entries)
- Days to follow up: 310 days; Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 43.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 46 kg; Height: 159 cm; BMI: 18.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol drinks per day: 0; Alcohol days per week: 0.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0510-D13-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0510-D13-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 3.
  Slide HCM-CSHL-0510-D13-01A-01-S1-HE: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 4.
- Sample HCM-CSHL-0510-D13-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0510-D13-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
- Sample HCM-CSHL-0510-D13-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 12.
